Somatic mutation profile of tumor specimen TCGA-10-0935-01A (aliquot TCGA-10-0935-01A-03W-0420-08) from TCGA case TCGA-10-0935, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.7 years (25,098 days).
Specimen TCGA-10-0935-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb753be7-9aad-44f3-970c-ae0e1bf352a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0935-11A (Solid Tissue Normal), aliquot TCGA-10-0935-11A-01W-0421-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/242da960-1f6e-4a45-9794-92419601ba66

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 127/132 reads (96%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKR1B1 | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV53649163; called by muse, mutect2, varscan2
- ANKS6 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs746432959, COSV100782226; called by muse, mutect2, varscan2
- BTBD3 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 339/639 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54779174; called by muse, mutect2, varscan2
- CLCN3 | c.2349C>G p.C783W | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV61628832; called by muse, varscan2
- COL3A1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs550665335, CM1512473, COSV58595485, COSV58597783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSDE1 | c.103A>C p.T35P | Missense Mutation (SNP) | VAF 228/1013 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV54762483; called by muse, mutect2, varscan2
- CTAGE1 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV101194452; called by muse, mutect2, varscan2
- CYP1B1 | c.1359C>G p.N453K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV52230307; called by mutect2, varscan2
- FCRL5 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 231/500 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as rs376321602, COSV62516000, COSV62519878; called by muse, mutect2, varscan2
- GABRA2 | c.1157C>G p.T386S | Missense Mutation (SNP) | VAF 248/538 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.134); catalogued as COSV62920641; called by muse, mutect2, varscan2
- GRIN2B | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205414; called by muse, mutect2, varscan2
- HTR1A | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1427412024, COSV60500218; called by muse, mutect2, varscan2
- ITPR2 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV54383705, COSV54387932; called by muse, mutect2, varscan2
- KLK1 | c.42dup p.T15Dfs*18 | Frame Shift Ins (INS) | VAF 20/178 reads (11%) | catalogued as rs758242614; called by mutect2, varscan2
- KRT1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52866986; called by muse, mutect2, varscan2
- MYH10 | c.4163A>G p.E1388G | Missense Mutation (SNP) | VAF 105/158 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52613006; called by muse, mutect2, varscan2
- NBPF3 | c.639C>G p.H213Q | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV59065451; called by muse, mutect2, varscan2
- NYNRIN | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs758876637, COSV66843565, COSV66844825; called by muse, mutect2, varscan2
- OR4F5 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 152/176 reads (86%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV58737200; called by muse, varscan2
- OR5H2 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 184/799 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100788665, COSV62351639; called by muse, mutect2, varscan2
- OR7G3 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59641231; called by muse, mutect2, varscan2
- PCDHGA12 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV52772522; called by muse, mutect2, varscan2
- PHACTR3 | c.280+1G>A p.X94_splice | Splice Site (SNP) | VAF 61/109 reads (56%) | catalogued as COSV63035209; called by muse, mutect2, varscan2
- PNLIP | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65042176; called by muse, mutect2, varscan2
- POLD3 | c.1146A>C p.K382N | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV55246246; called by muse, mutect2, varscan2
- PRPF3 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61396621; called by muse, mutect2, varscan2
- RNLS | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59301209; called by muse, mutect2, varscan2
- ROS1 | c.6316G>A p.A2106T | Missense Mutation (SNP) | VAF 205/217 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150262256; called by muse, mutect2, varscan2
- RTN2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1039418305, COSV55596398; called by muse, mutect2, varscan2
- SALL3 | c.3694G>A p.V1232I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760952537, COSV73306280; called by muse, mutect2, varscan2
- SLC7A6OS | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 181/196 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM146173, COSV50450822; called by muse, mutect2, varscan2
- SON | c.4883T>A p.V1628D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV51671857; called by muse, mutect2, varscan2
- SPRY1 | c.605T>C p.L202S | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376045682; called by muse, mutect2, varscan2
- SPTA1 | c.5202A>G p.I1734M | Missense Mutation (SNP) | VAF 258/490 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV63760773; called by muse, mutect2, varscan2
- TRIM69 | c.590T>C p.L197P (on ENST00000329464 / NM_182985.5; = p.L38P on NM_080745.5) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.701); catalogued as rs1472363977, COSV100274168; called by muse, mutect2, varscan2
- WHAMM | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 206/338 reads (61%) | catalogued as COSV54500110; called by muse, mutect2, varscan2
- ZFX | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs1288280252, COSV58450179; called by muse, mutect2, varscan2
- CPD | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH5 | c.11521_11533del p.Q3841Afs*11 | Frame Shift Del (DEL) | VAF 72/402 reads (18%) | called by mutect2, pindel, varscan2
- THTPA | c.597_598insTTTCCGGC p.R200Ffs*14 | Frame Shift Ins (INS) | VAF 21/74 reads (28%) | called by muse*, mutect2, varscan2*
- ACAD9 | c.1632G>T p.T544= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, varscan2
- GPR35 | c.648C>T p.A216= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- KMT2C | c.12165C>T p.I4055= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs1469188251, COSV51510692, COSV99030554; called by muse, mutect2
- LCP1 | c.1413G>A p.A471= | Silent (SNP) | VAF 41/458 reads (9%) | catalogued as rs141184605; called by muse, mutect2
- MYO16 | c.3510A>G p.R1170= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV62763605; called by muse, mutect2, varscan2
- OR5V1 | c.510C>T p.G170= | Silent (SNP) | VAF 136/423 reads (32%) | catalogued as COSV65830680; called by muse, mutect2, varscan2
- PRTG | c.150C>T p.V50= | Silent (SNP) | VAF 90/214 reads (42%) | catalogued as rs1041307506, COSV66841057; called by muse, mutect2, varscan2
- TTN | c.98979A>G p.P32993= (on ENST00000591111; = p.P25569= on NM_003319.4) | Silent (SNP) | VAF 56/292 reads (19%) | catalogued as COSV60391263; called by muse, mutect2, varscan2
- WHAMM | c.2334G>A p.E778= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV54500124, COSV99725243; called by muse, mutect2, varscan2
- ZNF658B | n.2151G>A | RNA (SNP) | VAF 215/1026 reads (21%) | called by muse, mutect2, varscan2
